Gene-level copy-number profile of tumor specimen TCGA-AJ-A3NF-01A from TCGA case TCGA-AJ-A3NF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.8 years (22,210 days).
Specimen TCGA-AJ-A3NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.60a0ae98-b745-414c-bae2-61d187479e19.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AJ-A3NF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d909897-6a15-402d-9084-7fc7c078a728

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 238; copy number 1: 13,053; copy number 2: 41,491; copy number 3: 3,858; copy number 4: 822; copy number 5: 161; copy number 6: 69; copy number 7: 44; copy number 8: 78.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AJ-A3NF-01A-11D-A227-01): tumor purity 0.24, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 238 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:12,020,829–12,143,830, 1 gene (within-gene range 0–1): MAP2K4.
- chr17:12,081,899–14,069,495, 24 genes: MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093, HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1.
- chr17:16,929,816–20,595,708, 213 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 352 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes, copy number 6: RNU6-904P, RPS16P3.
- chr2:147,930,396–151,508,013, 44 genes, copy number 7 (within-gene range 3–7): ORC4, MBD5, AC019226.1, AC019226.2, AC019070.1, USP12P2, RPS29P8, EPC2, RNU2-9P, UBBP3, KIF5C-AS1, RPS20P13, USP8P2, KIF5C, AC105402.1, LYPD6B, TXNP5, AC009230.1, FAM8A3P, LYPD6, RPL17P13, MMADHC, MMADHC-DT, RNU6-601P, LINC01931, AC016682.1, LINC01818, LINC01817, RND3, LINC01920, AC104777.2, AC104777.1, LINC02612, AC023469.2, AC023469.1, AC018731.1, FABP5P10, RBM43, NMI, TNFAIP6, MIR4773-1, MIR4773-2, RN7SL124P, RIF1.
- chr2:183,897,950–186,509,361, 24 genes, copy number 5: AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr4:106,525,401–108,035,174, 13 genes, copy number 5 (within-gene range 2–5): AC092445.1, ACTR6P1, DKK2, RAC1P5, AC104663.1, RNU6-551P, PAPSS1, SGMS2, CYP2U1-AS1, RNU6-733P, CYP2U1, AC096564.1, HADH.
- chr12:45,215,987–45,440,404, 1 gene, copy number 5 (within-gene range 1–5): ANO6.
- chr12:45,444,766–46,373,778, 14 genes, copy number 5: AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,407,166, 3 genes, copy number 5: AC025031.1, AC025031.4, AC025031.5.
- chr12:50,256,238–51,028,566, 22 genes, copy number 5 (within-gene range 3–5): RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2.
- chr12:69,212,108–74,664,141, 80 genes, copy number 5–6 (broad region; genes not listed).
- chr16:68,358,327–68,630,968, 12 genes, copy number 8: SMPD3, AC099521.2, AC099521.3, AC099521.1, Y_RNA, RPL35AP33, ZFP90, RNU4-36P, AC126773.3, AC126773.6, AC126773.1, AC126773.2.
- chr16:68,644,248–68,651,948, 2 genes, copy number 8: AC126773.4, AC126773.5.
- chr18:30,713,275–32,470,882, 49 genes, copy number 5–8: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr18:44,214,971–46,463,140, 34 genes, copy number 8: AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1.
- chr18:52,340,197–53,535,903, 1 gene, copy number 5 (within-gene range 3–5): DCC.
- chr18:53,237,101–53,237,190, 1 gene, copy number 5: MIR4528.
- chr19:14,053,363–14,942,448, 50 genes, copy number 5: PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.3, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2.

Autosomal genes at a single copy (total copy number 1): 12,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
